Somatic mutation profile of tumor specimen TCGA-FZ-5921-01A (aliquot TCGA-FZ-5921-01A-11D-1609-08) from TCGA case TCGA-FZ-5921, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 85.1 years (31,074 days).
Specimen TCGA-FZ-5921-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afa0dc70-db4a-4713-b286-04a904d90790.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FZ-5921-11A (Solid Tissue Normal), aliquot TCGA-FZ-5921-11A-01D-1609-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98c1aaf5-059e-4526-9c4f-b84534b31df7

The open-access MAF lists 72 somatic variants for this specimen: 51 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 43, Silent 21, Nonsense Mutation 5, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SACS | c.7276C>T p.R2426* | Nonsense Mutation (SNP) | VAF 53/239 reads (22%) | catalogued as rs786204750, CM107279, COSV66540415; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 51/297 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG5 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756734792, COSV99575586; called by muse, mutect2, varscan2
- ADD2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs373747708, COSV52464232; called by muse, mutect2
- ADGRF3 | c.1190C>T p.P397L (on ENST00000311519 / NM_001145168.1; = p.P198L on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs759947684, COSV100274655, COSV61049754; called by muse, mutect2
- ATR | c.5293G>T p.E1765* | Nonsense Mutation (SNP) | VAF 49/427 reads (11%) | catalogued as COSV100638524; called by muse, mutect2, varscan2
- BORCS6 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV101198021; called by muse, mutect2
- CDKL4 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 23/464 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs770898977, COSV66508842; called by muse, mutect2
- CRB2 | c.2252T>A p.L751H | Missense Mutation (SNP) | VAF 48/518 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV100749727; called by muse, mutect2
- DISP3 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1441790403, COSV53820638, COSV53821384; called by muse, mutect2
- DMRT3 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV99506039; called by muse, mutect2
- DMRT3 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs937264633, COSV99506051; called by muse, varscan2
- DNAI3 | c.1263+1G>A p.X421_splice | Splice Site (SNP) | VAF 27/488 reads (6%) | catalogued as rs1192226257, COSV99642320; called by muse, mutect2
- EN1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99727395; called by muse, mutect2
- EN1 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99727397; called by muse, mutect2, varscan2
- FCGBP | c.6629T>G p.L2210* | Nonsense Mutation (SNP) | VAF 90/1396 reads (6%) | catalogued as COSV99663776; called by muse, mutect2
- FRMD7 | c.1396A>C p.K466Q | Missense Mutation (SNP) | VAF 87/1277 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV100049230; called by muse, mutect2
- GFRA2 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs375798460, COSV60778678; called by muse, mutect2, varscan2
- GPR21 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101016508; called by muse, mutect2, varscan2
- GRIA1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs771987779, COSV99601921; called by muse, mutect2, varscan2
- HOXA7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 138/653 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1233857798, COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- IMPG1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 40/535 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64054719; called by muse, mutect2
- IQSEC1 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.686); catalogued as rs754774497, COSV99832275; called by muse, mutect2, varscan2
- KIAA1109 | c.4724T>G p.L1575R | Missense Mutation (SNP) | VAF 32/539 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV99173388; called by muse, mutect2
- KLK4 | c.612+1G>A p.X204_splice | Splice Site (SNP) | VAF 54/638 reads (8%) | catalogued as COSV100133701; called by muse, mutect2
- LAMA1 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs148234507; called by muse, mutect2
- LRP1B | c.9190C>T p.R3064* | Nonsense Mutation (SNP) | VAF 31/389 reads (8%) | catalogued as COSV67183688; called by muse, mutect2
- MMP3 | c.1401C>A p.H467Q | Missense Mutation (SNP) | VAF 69/550 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100242999; called by muse, mutect2, varscan2
- NAV3 | c.3130A>G p.S1044G | Missense Mutation (SNP) | VAF 79/642 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs901406977, COSV57088112, COSV99894741; called by muse, mutect2, varscan2
- NOS1 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 126/1313 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1228191948, COSV100501289; called by muse, mutect2
- OPN1LW | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064796643, COSV64063828; ClinVar: uncertain significance; called by muse, mutect2
- OR2L2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 84/1026 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV63548700; called by muse, mutect2
- PAQR3 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 28/535 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs776313637, COSV99785376; called by muse, mutect2
- PARVB | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs749414411, COSV58689285, COSV58689308; called by muse, mutect2
- PITPNM3 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99339210; called by muse, mutect2
- PYHIN1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV100932405; called by muse, mutect2, varscan2
- QRICH2 | c.1053G>T p.L351F | Missense Mutation (SNP) | VAF 100/536 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.116); catalogued as COSV99429630; called by muse, mutect2, varscan2
- SALL1 | c.2900G>T p.G967V | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99179941; called by muse, mutect2, varscan2
- SCN5A | c.5368G>A p.D1790N (on ENST00000333535 / NM_198056.3; = p.D1789N on NM_000335.5) | Missense Mutation (SNP) | VAF 31/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772508476, CM1211224, COSV61122115; ClinVar: uncertain significance; called by muse, mutect2
- SELP | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 56/724 reads (8%) | catalogued as COSV55258636; called by muse, mutect2
- SH3TC1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752988270, COSV99795267; called by muse, mutect2, varscan2
- SMO | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 77/487 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.446); catalogued as COSV50825057, COSV99977036; called by muse, mutect2, varscan2
- SORCS3 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs868423005, COSV63803356; called by muse, mutect2
- SPTLC3 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 56/866 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100983272; called by muse, mutect2
- SQSTM1 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.914); catalogued as COSV100657711; called by muse, mutect2
- TERT | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57223154, COSV99720390; called by muse, mutect2
- ZC3H4 | c.2992G>A p.V998M | Missense Mutation (SNP) | VAF 38/527 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs774730626, COSV99452708; called by muse, mutect2
- ZFHX4 | c.8452G>A p.E2818K | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50697960; called by muse, mutect2, varscan2
- ZNF208 | c.1318C>A p.L440I | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101237184, COSV68101703; called by muse, mutect2
- PI4KB | c.2347_2349del p.E783del (on ENST00000368873 / NM_001369623.1; = p.E795del on NM_002651.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 54/406 reads (13%) | called by pindel, varscan2
- ADGRB3 | c.1438A>C p.R480= | Silent (SNP) | VAF 32/474 reads (7%) | catalogued as COSV101001798; called by muse, mutect2
- AHNAK2 | c.2730C>T p.A910= | Silent (SNP) | VAF 123/1600 reads (8%) | catalogued as rs149453124, COSV100319296; called by muse, mutect2
- ATP10A | c.4260C>A p.T1420= | Silent (SNP) | VAF 59/340 reads (17%) | catalogued as COSV100791476, COSV63519319; called by muse, mutect2, varscan2
- ATP4A | c.1083C>G p.R361= | Silent (SNP) | VAF 113/1044 reads (11%) | catalogued as COSV99382987; called by muse, mutect2, varscan2
- BMP3 | c.855G>A p.R285= | Silent (SNP) | VAF 34/411 reads (8%) | catalogued as rs1355769621, COSV51083218; called by muse, mutect2
- C16orf46 | c.721C>T p.L241= | Silent (SNP) | VAF 66/986 reads (7%) | catalogued as COSV100215445; called by muse, mutect2
- C16orf46 | c.720G>C p.V240= | Silent (SNP) | VAF 67/987 reads (7%) | catalogued as COSV100215447; called by muse, mutect2
- CYP11A1 | c.813C>T p.D271= | Silent (SNP) | VAF 198/1152 reads (17%) | catalogued as rs371896933; called by muse, mutect2, varscan2
- DNAH17 | c.9717C>T p.A3239= | Silent (SNP) | VAF 130/1507 reads (9%) | catalogued as rs139000751; called by muse, mutect2
- DPPA4 | c.204G>A p.E68= | Silent (SNP) | VAF 52/710 reads (7%) | catalogued as COSV100169670; called by muse, mutect2
- FAAP24 | c.498C>T p.I166= | Silent (SNP) | VAF 103/731 reads (14%) | catalogued as COSV99578189; called by muse, mutect2, varscan2
- FILIP1 | c.3102G>A p.R1034= | Silent (SNP) | VAF 89/987 reads (9%) | catalogued as COSV99385910; called by muse, mutect2
- GPR135 | c.987G>A p.T329= | Silent (SNP) | VAF 9/191 reads (5%) | catalogued as COSV67749970; called by muse, mutect2
- HEPHL1 | c.2592T>C p.Y864= | Silent (SNP) | VAF 25/248 reads (10%) | catalogued as rs374558812; called by muse, mutect2
- KCNN2 | c.423C>T p.F141= (on ENST00000264773; = p.F353= on NM_021614.4) | Silent (SNP) | VAF 13/249 reads (5%) | catalogued as rs1219220191, COSV53299636, COSV99300593; called by muse, mutect2
- MCM10 | c.1644C>T p.S548= (on ENST00000484800 / NM_182751.3; = p.S547= on NM_018518.5) | Silent (SNP) | VAF 39/406 reads (10%) | catalogued as COSV101098401; called by muse, mutect2
- PCIF1 | c.1536C>T p.F512= | Silent (SNP) | VAF 53/792 reads (7%) | catalogued as rs753235115, COSV59816052; called by muse, mutect2
- PLCD3 | c.1302C>T p.C434= | Silent (SNP) | VAF 25/328 reads (8%) | catalogued as rs369060547; called by muse, mutect2
- POTEF | c.2448C>T p.R816= | Silent (SNP) | VAF 44/862 reads (5%) | catalogued as rs562326654, COSV100665255, COSV62545450; called by muse, mutect2
- PRKCQ | c.6G>A p.S2= | Silent (SNP) | VAF 24/313 reads (8%) | catalogued as rs201768145, COSV99577696; called by muse, mutect2
- TIMD4 | c.414G>A p.T138= | Silent (SNP) | VAF 88/1339 reads (7%) | catalogued as rs1188048455, COSV50857852; called by muse, mutect2
